Gene-level copy-number profile of specimen HCM-CSHL-0768-C56-85B from HCMI case HCM-CSHL-0768-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage II; Tumor grade: High Grade.
Specimen HCM-CSHL-0768-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7e4f163f-5eae-445d-991d-fa2e1559bbf5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0768-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,250 have no estimate.
https://portal.gdc.cancer.gov/files/a76386f8-81f3-4716-a29d-b2bbc93521c0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 116; copy number 2: 20,725; copy number 3: 28,633; copy number 4: 6,305; copy number 5: 507; copy number 6: 307; copy number 7: 2; copy number 8: 46; copy number 9: 1,562; copy number 10: 13; copy number 11: 7; copy number 12: 1; copy number 13: 16; copy number 14: 4; copy number 24: 9; copy number 29: 26; copy number 36: 12; copy number 46: 1; copy number 54: 21; copy number 58: 3.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–48,599,436, 6 genes (within-gene range 0–2): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.
- chr14:106,257,762–106,324,760, 14 genes (within-gene range 0–3): IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26, IGHVIII-26-1, IGHVII-26-2, IGHV7-27, IGHV4-28.
- chr17:11,977,439–12,021,508, 2 genes (within-gene range 0–2): ZNF18, AC005410.1.
- chr17:12,036,496–12,036,637, 1 gene (within-gene range 0–2): RNU11-2P.
- chr17:36,165,681–36,457,535, 15 genes (within-gene range 0–2): TBC1D3B, AC243829.1, CCL3L3, CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J.
- chr22:18,400,407–18,757,906, 18 genes: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,723 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:631,074–632,616, 2 genes, copy number 10 (within-gene range 3–10): MTCO1P12, AC114498.2.
- chr1:633,535–634,922, 3 genes, copy number 10 (within-gene range 3–10): MTATP8P1, MTATP6P1, MTCO3P12.
- chr6:29,934,101–29,934,286, 1 gene, copy number 7: HLA-U.
- chr6:62,460,940–62,461,503, 1 gene, copy number 7: DHFRP5.
- chr8:39,451,045–145,066,685, 1,594 genes, copy number 9–24 (broad region; genes not listed).
- chr9:64,765,054–64,765,535, 1 gene, copy number 8: IGKV1OR-2.
- chr12:17,066,368–17,709,867, 8 genes, copy number 10: AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378.
- chr12:19,089,151–23,251,499, 65 genes, copy number 8–58 (broad region; genes not listed).
- chr12:24,566,964–26,421,462, 45 genes, copy number 29–54 (within-gene range 3–54): LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1.
- chr12:26,335,864–26,373,733, 2 genes, copy number 29 (within-gene range 3–29): AC055720.2, RNA5SP354.
- chr12:37,575,587–37,576,384, 1 gene, copy number 12: ZNF970P.

Autosomal genes at a single copy (total copy number 1): 106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
